Gene-level copy-number profile of tumor specimen TCGA-59-2354-01A from TCGA case TCGA-59-2354, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3.
Specimen TCGA-59-2354-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.786c5533-6c42-469a-a7eb-9a3feefdfdcb.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-59-2354-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/dd0e22bb-92c2-4596-98ab-33a5e55dc61f

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 20; copy number 1: 16,240; copy number 2: 39,048; copy number 3: 3,692; copy number 4: 817.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-59-2354-01A-01D-0704-01): tumor purity 0.64, ploidy 1.84, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 20 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:129,282,458–129,791,837, 20 genes (within-gene range 0–1): AL161785.1, C9orf106, AL353803.5, LINC01503, RN7SL159P, AL353803.3, AL353803.2, AL353803.1, LINC00963, AL353803.4, AL391056.2, AL391056.1, NTMT1, C9orf50, ASB6, AL590369.1, PRRX2, PRRX2-AS1, PTGES, UBE2V1P4.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 16,050. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
